Gene-level copy-number profile of tumor specimen TCGA-CI-6621-01A from TCGA case TCGA-CI-6621, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.6 years (23,240 days).
Specimen TCGA-CI-6621-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.87c670ef-bda7-4bac-a88c-54c0d59122a4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CI-6621-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3def45e3-0f48-4930-b8e9-1259737cadb8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,773; copy number 2: 39,459; copy number 3: 6,148; copy number 4: 392; copy number 5: 1,048.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CI-6621-01A-11D-1825-01): tumor purity 0.46, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,048 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:50,093,279–55,433,742, 67 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:88,759,700–89,338,528, 1 gene, copy number 5 (within-gene range 2–5): ZNF804B.
- chr7:89,443,946–90,238,137, 7 genes, copy number 5: AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2.
- chr7:90,251,923–90,252,020, 1 gene, copy number 5: Y_RNA.
- chr7:129,117,513–130,791,724, 54 genes, copy number 5: CYCSP20, AC011005.1, TSPAN33, RNY1P11, SMO, AC011005.4, AHCYL2, AC009244.1, CDC26P1, STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5.
- chr7:130,822,868–130,939,661, 9 genes, copy number 5 (within-gene range 2–5): AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1.
- chr7:136,685,559–137,182,107, 1 gene, copy number 5 (within-gene range 2–5): AC009264.1.
- chr7:136,868,669–137,164,612, 4 genes, copy number 5 (within-gene range 2–5): CHRM2, MIR490, KRT8P51, AC009517.1.
- chr7:155,474,256–155,644,406, 1 gene, copy number 5 (within-gene range 2–5): AC009403.2.
- chr7:155,534,964–155,812,463, 4 genes, copy number 5: AC009403.3, AC009403.1, RBM33, SHH.
- chr20:30,214,765–64,313,132, 899 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,392. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
